Somatic mutation profile of tumor specimen C3N-01019-03 (aliquot CPT0117680009) from CPTAC case C3N-01019, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 56.3 years (20,550 days).
Specimen C3N-01019-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f248c71b-cf96-4c17-87e3-b0d632bcf7e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01019-31 (Blood Derived Normal), aliquot CPT0118910002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f99f3c22-7a0a-40b3-8f5c-0a10fb379411

The open-access MAF lists 913 somatic variants for this specimen: 619 protein-altering or splice-affecting, 179 silent, 115 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 524, Silent 179, Intron 45, Nonsense Mutation 38, RNA 28, Splice Site 20, Frame Shift Del 19, 5'UTR 14, 3'UTR 10, 5'Flank 10, Splice Region 9, 3'Flank 8.

Variants (750 of 913; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 75/229 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA5 | c.3639G>A p.S1213= | Splice Region (SNP) | VAF 18/146 reads (12%) | catalogued as rs778958910, COSV67018547; called by muse, mutect2, varscan2
- ACAD11 | c.646G>T p.E216* | Nonsense Mutation (SNP) | VAF 32/125 reads (26%) | catalogued as COSV53893627; called by muse, mutect2, varscan2
- ACAN | c.5317C>A p.L1773I | Missense Mutation (SNP) | VAF 84/366 reads (23%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.661); catalogued as rs767359295, COSV61357916, COSV61369764; called by mutect2, varscan2
- ACIN1 | c.2143G>A p.A715T | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs372380278; called by muse, mutect2, varscan2
- ACTN2 | c.2594G>T p.R865M | Missense Mutation (SNP) | VAF 72/363 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV100856629; called by muse, mutect2, varscan2
- ACTN2 | c.2595G>T p.R865S | Missense Mutation (SNP) | VAF 72/368 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.083); catalogued as COSV100856631; called by muse, mutect2, varscan2
- ADNP | c.2496_2499del p.N832Kfs*81 | Frame Shift Del (DEL) | VAF 116/268 reads (43%) | catalogued as rs587777523; called by pindel, varscan2
- AMFR | c.139G>T p.D47Y | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as rs879120776; called by muse, mutect2, varscan2
- AMPD1 | c.1463G>T p.W488L | Missense Mutation (SNP) | VAF 51/252 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100815168; called by muse, mutect2, varscan2
- APOA4 | c.160C>A p.L54I | Missense Mutation (SNP) | VAF 85/354 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.401); catalogued as COSV63359993; called by muse, mutect2, varscan2
- ARHGAP17 | c.822G>T p.M274I | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV51510300; called by muse, varscan2
- ARHGAP33 | c.3199C>T p.P1067S | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs752933278; called by muse, mutect2, varscan2
- ARHGEF11 | c.2602C>T p.R868W | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59356859; called by muse, mutect2, varscan2
- ARHGEF18 | c.1591G>T p.D531Y (on ENST00000359920 / NM_001130955.2; = p.D427Y on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV60470721; called by muse, mutect2, varscan2
- ASAH2 | c.609C>A p.F203L | Missense Mutation (SNP) | VAF 84/435 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.241); catalogued as rs893853750; called by muse, mutect2, varscan2
- ASPM | c.5084G>T p.R1695L | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs541097917, COSV54126321; called by muse, mutect2, varscan2
- ASPM | c.4583A>T p.K1528M | Missense Mutation (SNP) | VAF 49/292 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as CD033167, COSV54134032; called by muse, mutect2, varscan2
- ATM | c.875C>A p.P292Q | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM980134, COSV53732933, COSV53769959; called by muse, mutect2, varscan2
- ATP1A4 | c.3022G>A p.D1008N | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV63623911; called by muse, mutect2, varscan2
- ATP2B2 | c.205C>A p.P69T | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV59499679; called by muse, mutect2, varscan2
- AUTS2 | c.2371G>A p.E791K | Missense Mutation (SNP) | VAF 58/329 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100716898; called by muse, mutect2, varscan2
- AXIN1 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs372115709; called by muse, mutect2, varscan2
- AXIN1 | c.926G>A p.G309D | Missense Mutation (SNP) | VAF 57/224 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1267777388, COSV99250023; called by muse, mutect2, varscan2
- B3GNT3 | c.670C>A p.L224M | Missense Mutation (SNP) | VAF 53/237 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1002782487; called by muse, mutect2, varscan2
- BNIP5 | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 106/356 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as COSV71325476; called by muse, mutect2, varscan2
- BTK | c.83G>T p.R28L | Missense Mutation (SNP) | VAF 77/191 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM021959, CM940183, CM960197; called by muse, mutect2, varscan2
- C4orf54 | c.766C>T p.Q256* | Nonsense Mutation (SNP) | VAF 30/140 reads (21%) | catalogued as COSV72766956; called by muse, mutect2, varscan2
- C6orf163 | c.758A>T p.K253I | Missense Mutation (SNP) | VAF 50/205 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.472); catalogued as rs1168261505; called by muse, mutect2, varscan2
- CACNG3 | c.932G>C p.R311P | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50068726, COSV50070085, COSV50078325; called by muse, mutect2, varscan2
- CAMSAP3 | c.195C>G p.Y65* | Nonsense Mutation (SNP) | VAF 27/93 reads (29%) | catalogued as COSV50339343; called by muse, mutect2, varscan2
- CAND2 | c.943A>T p.N315Y (on ENST00000456430 / NM_001162499.2; = p.N222Y on NM_012298.3) | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs749406971; called by muse, mutect2, varscan2
- CATSPERD | c.1333G>C p.G445R | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100486971; called by muse, mutect2, varscan2
- CCL22 | c.186G>T p.R62S | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.702); catalogued as rs1567549323; called by muse, mutect2, varscan2
- CD109 | c.2159G>T p.W720L | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1014238400, COSV99754308; called by muse, mutect2, varscan2
- CDC20B | c.1495C>A p.P499T (on ENST00000381375 / NM_001170402.1; = p.P495T on NM_152623.2) | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1283993780; called by muse, mutect2, varscan2
- CDH10 | c.1986del p.G663Efs*13 | Frame Shift Del (DEL) | VAF 61/348 reads (18%) | catalogued as COSV52580055; called by mutect2, pindel, varscan2
- CDH9 | c.1720G>A p.D574N | Missense Mutation (SNP) | VAF 53/272 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as rs867964392, COSV50259663; called by muse, mutect2, varscan2
- CDK18 | c.617G>T p.R206L (on ENST00000506784 / NM_212503.3; = p.R176L on NM_002596.4) | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774600930, COSV63727905; called by muse, mutect2, varscan2
- CELSR2 | c.7235G>A p.R2412Q | Missense Mutation (SNP) | VAF 57/317 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as rs1409978941, COSV54766144; called by muse, mutect2, varscan2
- CHD6 | c.2316C>G p.D772E | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.562); catalogued as COSV58557052; called by muse, mutect2, varscan2
- CHD8 | c.4652G>A p.W1551* (on ENST00000646647 / NM_001170629.2; = p.W1272* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 46/235 reads (20%) | catalogued as rs1555314290, COSV63219095; called by muse, mutect2, varscan2
- CLCN1 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 93/458 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV58371123; called by muse, mutect2, varscan2
- CLDN11 | c.596del p.P199Rfs*21 | Frame Shift Del (DEL) | VAF 42/249 reads (17%) | catalogued as COSV50355319; called by mutect2, pindel, varscan2
- CLINT1 | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 46/217 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV51627049; called by muse, mutect2, varscan2
- CMTR2 | c.1937C>T p.P646L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57603399; called by muse, mutect2, varscan2
- CNGA4 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 45/174 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV56411397; called by muse, mutect2, varscan2
- COL3A1 | c.4168C>A p.L1390M | Missense Mutation (SNP) | VAF 44/240 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV100482687; called by muse, mutect2, varscan2
- COL7A1 | c.2912C>T p.S971L | Missense Mutation (SNP) | VAF 68/344 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs374082591; called by muse, mutect2, varscan2
- COMMD3-BMI1 | c.31T>G p.F11V | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1346952900; called by muse, mutect2, varscan2
- CPA3 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV56044360; called by muse, mutect2, varscan2
- CPN2 | c.985C>G p.P329A | Missense Mutation (SNP) | VAF 37/258 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); catalogued as COSV60469952; called by muse, mutect2, varscan2
- CPZ | c.442C>A p.R148S (on ENST00000360986 / NM_001014447.3; = p.R137S on NM_003652.3) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as rs377251041; called by muse, mutect2
- CRHR1 | c.278G>T p.W93L | Missense Mutation (SNP) | VAF 45/244 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1386239990; called by muse, mutect2, varscan2
- DBH | c.870C>A p.D290E | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1564209603; called by muse, mutect2, varscan2
- DCBLD2 | c.1895C>T p.T632I | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as rs1445451821; called by muse, mutect2, varscan2
- DGKB | c.2030C>A p.S677Y | Missense Mutation (SNP) | VAF 67/174 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV51783265; called by muse, mutect2, varscan2
- DNAH5 | c.3451G>T p.G1151* | Nonsense Mutation (SNP) | VAF 48/216 reads (22%) | catalogued as COSV54225094; called by muse, mutect2, varscan2
- DNAJC13 | c.2065G>T p.D689Y | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53458680; called by muse, mutect2, varscan2
- DNASE1L3 | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 25/239 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.155); catalogued as COSV100568625; called by muse, mutect2, varscan2
- DOP1B | c.2502G>T p.K834N | Missense Mutation (SNP) | VAF 94/451 reads (21%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.529); catalogued as rs1029935193, COSV67694115; called by muse, mutect2, varscan2
- DPP6 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs564612979; called by muse, mutect2, varscan2
- DUSP11 | c.106G>T p.D36Y | Missense Mutation (SNP) | VAF 74/431 reads (17%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as rs770486275; called by muse, varscan2
- DZIP1L | c.962G>T p.R321L | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV59519796; called by muse, mutect2
- EDEM3 | c.722G>T p.R241L | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV58923253; called by muse, varscan2
- EDEM3 | c.721C>T p.R241* | Nonsense Mutation (SNP) | VAF 24/155 reads (15%) | catalogued as COSV58924212; called by muse, mutect2, varscan2
- EHMT1 | c.3199G>A p.D1067N | Missense Mutation (SNP) | VAF 109/515 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.35); catalogued as rs751091478; called by muse, mutect2, varscan2
- EPHB6 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 48/273 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs1191178441; called by muse, mutect2, varscan2
- EVPLL | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.063); catalogued as rs762851483; called by muse, mutect2, varscan2
- FAM13C | c.1251C>A p.D417E | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.102); catalogued as rs1464341765; called by muse, mutect2, varscan2
- FAM71E2 | c.2467C>A p.P823T | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs774914586; called by mutect2, varscan2
- FBN2 | c.2909G>T p.R970L | Missense Mutation (SNP) | VAF 63/358 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs368402648; called by muse, mutect2, varscan2
- FLG2 | c.986G>A p.C329Y | Missense Mutation (SNP) | VAF 43/268 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs759428841; called by muse, mutect2, varscan2
- FOXD3 | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 87/350 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.316); catalogued as rs1463307763, COSV64380230; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.676G>T p.D226Y | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV100437771, COSV58552084; called by muse, mutect2, varscan2
- FPR1 | c.246G>T p.M82I | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59052231; called by muse, mutect2
- FUT2 | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 65/352 reads (18%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs774871775, COSV67179133; called by muse, mutect2, varscan2
- GABRB3 | c.910A>G p.K304E | Missense Mutation (SNP) | VAF 67/307 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555401426, COSV54686121; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GABRG3 | c.1237G>T p.D413Y | Missense Mutation (SNP) | VAF 87/397 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV61521690; called by muse, mutect2, varscan2
- GALNT15 | c.833T>C p.V278A | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1347820053; called by muse, mutect2, varscan2
- GHSR | c.640G>T p.V214L | Missense Mutation (SNP) | VAF 53/333 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as rs755270773, COSV53837642; called by muse, mutect2, varscan2
- GLYR1 | c.1135G>A p.G379R | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs939726996, COSV58925665; called by muse, mutect2, varscan2
- GPRC6A | c.1952T>A p.I651N | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs539074479; called by muse, mutect2, varscan2
- GRIN2B | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV74205531; called by muse, mutect2, varscan2
- GTF2E1 | c.907G>T p.D303Y | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV52205258; called by muse, mutect2, varscan2
- HECW1 | c.2303C>A p.P768Q | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.005); catalogued as COSV101222945; called by muse, mutect2, varscan2
- HERC1 | c.11782G>A p.E3928K | Missense Mutation (SNP) | VAF 71/265 reads (27%) | SIFT tolerated (0.87); PolyPhen benign (0.037); catalogued as COSV71249898; called by muse, mutect2, varscan2
- HSD17B7 | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 58/326 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780864653; called by muse, mutect2, varscan2
- IGHV1-46 | c.115G>T p.V39F | Missense Mutation (SNP) | VAF 74/342 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as rs61747196; called by muse, mutect2, varscan2
- IGHV3-33 | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.737); catalogued as rs1555493827; called by muse, mutect2, varscan2
- INPP4B | c.836G>T p.R279I | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99525187; called by muse, mutect2
- IRF8 | c.803G>T p.R268L | Missense Mutation (SNP) | VAF 75/253 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV51896629, COSV51899822; called by muse, mutect2, varscan2
- ITGA8 | c.1970del p.P657Qfs*6 | Frame Shift Del (DEL) | VAF 24/128 reads (19%) | catalogued as COSV100959555; called by mutect2, pindel, varscan2
- ITIH2 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 42/212 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761768242; called by muse, mutect2, varscan2
- KCNS2 | c.853C>A p.P285T | Missense Mutation (SNP) | VAF 77/211 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.157); catalogued as COSV54638752; called by muse, mutect2, varscan2
- KCP | c.4301G>C p.C1434S (on ENST00000620378; = p.C1558S on NM_001366122.1) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52820675; called by muse, mutect2, varscan2
- KEAP1 | c.283G>T p.A95S | Missense Mutation (SNP) | VAF 47/218 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV50288374, COSV50635765; called by muse, mutect2, varscan2
- KIAA0232 | c.1454G>T p.G485V | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV56924657; called by muse, mutect2, varscan2
- KLF17 | c.345G>C p.Q115H | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs149226855; called by muse, mutect2, varscan2
- KMT2B | c.2116C>T p.R706* | Nonsense Mutation (SNP) | VAF 8/180 reads (4%) | catalogued as COSV52890581; called by muse, mutect2
- KMT2C | c.9968A>G p.H3323R | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as rs778241763, COSV51466407; called by muse, mutect2, varscan2
- KMT2D | c.11080G>T p.G3694C | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs751558457; called by mutect2, varscan2
- KRTAP13-2 | c.476C>A p.S159Y | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV67762150; called by muse, mutect2, varscan2
- LAMB3 | c.372G>A p.Q124= | Splice Region (SNP) | VAF 57/447 reads (13%) | catalogued as rs759819148; called by muse, mutect2, varscan2
- LIMK1 | c.1823G>T p.R608L | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100283380; called by muse, mutect2, varscan2
- LMTK2 | c.104-1G>T p.X35_splice | Splice Site (SNP) | VAF 19/94 reads (20%) | catalogued as COSV52006310; called by muse, mutect2, varscan2
- LOXHD1 | c.3321A>G p.I1107M | Missense Mutation (SNP) | VAF 41/217 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV56068409; called by muse, mutect2, varscan2
- LRP1B | c.12979C>A p.H4327N | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.021); catalogued as rs961678930, COSV101249169; called by muse, mutect2, varscan2
- MAG | c.1453C>T p.R485C | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.563); catalogued as rs531785357, COSV62700188, COSV62701465; called by muse, mutect2
- MAGEB4 | c.473C>G p.T158R | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as COSV66775163, COSV66776098; called by muse, mutect2, varscan2
- MANEA | c.1178G>T p.R393L | Missense Mutation (SNP) | VAF 50/200 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs776851480, COSV100721674, COSV62589766; called by muse, mutect2, varscan2
- MARK1 | c.2291G>C p.R764P | Missense Mutation (SNP) | VAF 32/220 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100857600; called by muse, varscan2
- MED16 | c.943G>T p.G315* | Nonsense Mutation (SNP) | VAF 43/216 reads (20%) | catalogued as COSV99515757; called by muse, mutect2, varscan2
- MMRN1 | c.550C>T p.L184F | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.889); catalogued as COSV99307376; called by muse, mutect2, varscan2
- MPEG1 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1440597204, COSV57096223; called by muse, mutect2, varscan2
- MROH9 | c.1480C>A p.L494I | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV63012788; called by muse, mutect2, varscan2
- MS4A14 | c.763C>G p.L255V | Missense Mutation (SNP) | VAF 41/280 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.035); catalogued as rs1175934608; called by muse, mutect2, varscan2
- MUC16 | c.37219C>A p.H12407N | Missense Mutation (SNP) | VAF 44/181 reads (24%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.005); catalogued as COSV101198672; called by muse, mutect2, varscan2
- MUC16 | c.28837C>A p.P9613T | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV67447249; called by muse, mutect2, varscan2
- MYBPC1 | c.995C>T p.S332F (on ENST00000550270 / NM_206820.2; = p.S357F on NM_002465.4) | Missense Mutation (SNP) | VAF 51/276 reads (18%) | SIFT tolerated (1); PolyPhen probably damaging (0.974); catalogued as COSV100638350; called by muse, mutect2, varscan2
- NAXE | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 77/497 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371165027; called by muse, mutect2, varscan2
- NEB | c.14303G>C p.R4768P | Missense Mutation (SNP) | VAF 65/351 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as rs556624010, COSV99429480; called by muse, mutect2, varscan2
- NF1 | c.8024del p.P2675Qfs*4 (on ENST00000358273 / NM_001042492.3; = p.P2654Qfs*4 on NM_000267.3) | Frame Shift Del (DEL) | VAF 34/334 reads (10%) | catalogued as COSV62199827; called by pindel, varscan2
- NLGN1 | c.909G>T p.W303C | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100849991; called by muse, mutect2, varscan2
- NLRP5 | c.2794G>A p.D932N | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1295292825, COSV66763523; called by muse, mutect2, varscan2
- NVL | c.760G>T p.G254W | Missense Mutation (SNP) | VAF 16/193 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV55875327; called by muse, mutect2
- OBSCN | c.11665C>A p.Q3889K | Missense Mutation (SNP) | VAF 44/233 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as COSV52802069; called by muse, mutect2, varscan2
- OR1M1 | c.730C>A p.H244N | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101447593; called by muse, mutect2, varscan2
- OR2M5 | c.567C>A p.C189* | Nonsense Mutation (SNP) | VAF 51/263 reads (19%) | catalogued as COSV63546424; called by muse, mutect2, varscan2
- OR2W3 | c.482C>A p.P161H | Missense Mutation (SNP) | VAF 43/218 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1259316951, COSV64456693; called by muse, mutect2, varscan2
- OR4C12 | c.256G>T p.E86* | Nonsense Mutation (SNP) | VAF 55/269 reads (20%) | catalogued as COSV58861101; called by muse, mutect2, varscan2
- OR5M8 | c.540C>A p.D180E | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100510773; called by muse, mutect2, varscan2
- PAPPA2 | c.4641C>A p.D1547E | Missense Mutation (SNP) | VAF 85/478 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.561); catalogued as COSV62792028; called by muse, mutect2, varscan2
- PARP6 | c.1645C>T p.R549* | Nonsense Mutation (SNP) | VAF 44/154 reads (29%) | catalogued as rs372747393; called by muse, mutect2, varscan2
- PAX4 | c.922C>A p.P308T | Missense Mutation (SNP) | VAF 64/260 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.096); catalogued as COSV58388699; called by muse, mutect2, varscan2
- PCDH11X | c.517G>T p.V173F | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53484395; called by muse, mutect2, varscan2
- PCDH18 | c.2929G>T p.G977C | Missense Mutation (SNP) | VAF 43/247 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV61266272; called by muse, mutect2, varscan2
- PCDHB10 | c.2345G>A p.G782E | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as rs782586446; called by muse, varscan2
- PCDHB13 | c.527A>G p.N176S | Missense Mutation (SNP) | VAF 59/402 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.764); catalogued as rs370178677, COSV99506495; called by muse, mutect2, varscan2
- PCDHGA1 | c.1990G>C p.V664L | Missense Mutation (SNP) | VAF 78/435 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.273); catalogued as rs768240411, COSV65296000; called by muse, mutect2, varscan2
- PCDHGA3 | c.2220T>A p.F740L | Missense Mutation (SNP) | VAF 74/413 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.049); catalogued as rs1235801833; called by muse, mutect2, varscan2
- PCDHGA8 | c.823G>T p.G275* | Nonsense Mutation (SNP) | VAF 46/241 reads (19%) | catalogued as COSV99548240; called by muse, mutect2, varscan2
- PDE11A | c.1976G>T p.R659L | Missense Mutation (SNP) | VAF 73/383 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760731175, COSV99615305; called by muse, mutect2, varscan2
- PHF24 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1324792315, COSV54276576; called by muse, mutect2
- PIGS | c.436G>C p.V146L | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.341); catalogued as rs146259850; called by muse, mutect2, varscan2
- PLA2G2E | c.211C>A p.R71S | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.155); catalogued as rs780494033, COSV64290582; called by muse, mutect2, varscan2
- PLCD1 | c.2057C>T p.T686M | Missense Mutation (SNP) | VAF 106/509 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs202132647, COSV52184226; called by muse, mutect2, varscan2
- PLK2 | c.19A>G p.I7V | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.011); catalogued as rs757948197, COSV57107657; called by muse, mutect2
- PLXNA4 | c.605G>T p.R202L | Missense Mutation (SNP) | VAF 53/264 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58141798; called by muse, mutect2, varscan2
- POM121L12 | c.511G>T p.D171Y | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV68692584; called by muse, mutect2, varscan2
- POT1 | c.802G>T p.G268C | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62931333; called by muse, mutect2, varscan2
- POTEG | c.1061G>A p.C354Y | Missense Mutation (SNP) | VAF 36/656 reads (5%) | SIFT tolerated (0.98); PolyPhen probably damaging (0.999); catalogued as rs758608644; called by muse, mutect2
- POU5F2 | c.129G>T p.R43S | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs769448417; called by muse, mutect2, varscan2
- PPP4R4 | c.2437C>T p.L813F | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs561344922; called by muse, mutect2, varscan2
- PPP6R2 | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as rs760976671; called by muse, mutect2, varscan2
- PRDM9 | c.1012C>A p.Q338K | Missense Mutation (SNP) | VAF 76/389 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV57005371; called by muse, mutect2, varscan2
- PROCA1 | c.262C>T p.R88C (on ENST00000439862 / NM_001366301.1; = p.R60C on NM_152465.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs776997644, COSV56386848; called by muse, mutect2, varscan2
- PRR35 | c.1013T>A p.L338Q | Missense Mutation (SNP) | VAF 47/249 reads (19%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.838); catalogued as rs1371595694; called by muse, mutect2, varscan2
- PRSS1 | c.648G>T p.W216C | Missense Mutation (SNP) | VAF 79/380 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100298675, COSV61193465; called by muse, mutect2, varscan2
- PTCHD1 | c.1690A>G p.I564V | Missense Mutation (SNP) | VAF 78/228 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV65062680; called by muse, mutect2, varscan2
- PTCHD3 | c.667C>A p.P223T | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.138); catalogued as COSV101438939; called by muse, mutect2, varscan2
- PTPRN2 | c.1093G>T p.D365Y | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs770180790; called by muse, mutect2, varscan2
- RASAL1 | c.375G>T p.Q125H | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV55658357; called by muse, mutect2, varscan2
- RDH8 | c.62T>C p.M21T (on ENST00000651512; = p.M1? on NM_015725.4) | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1366015625; called by muse, mutect2, varscan2
- RNF26 | c.146C>A p.T49K | Missense Mutation (SNP) | VAF 56/228 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.103); catalogued as COSV100264938; called by muse, mutect2, varscan2
- RPA4 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV100234405; called by muse, mutect2, varscan2
- RYR1 | c.8332G>T p.G2778* | Nonsense Mutation (SNP) | VAF 35/254 reads (14%) | catalogued as COSV62098045; called by muse, mutect2, varscan2
- SAMD9L | c.656A>G p.N219S | Missense Mutation (SNP) | VAF 45/227 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as rs1236779822; called by muse, mutect2, varscan2
- SCAI | c.418C>T p.R140C (on ENST00000336505 / NM_001144877.3; = p.R163C on NM_173690.5) | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); catalogued as rs1161510823; called by muse, mutect2, varscan2
- SCN3A | c.4799C>G p.S1600C | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51814303; called by muse, mutect2, varscan2
- SH3TC1 | c.1992G>T p.E664D | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs765485104; called by muse, mutect2, varscan2
- SHANK1 | c.5829C>A p.N1943K | Missense Mutation (SNP) | VAF 42/282 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs1035763147; called by muse, mutect2, varscan2
- SHROOM3 | c.2627G>T p.R876L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as COSV56041276; called by muse, mutect2, varscan2
- SLITRK5 | c.2155G>C p.G719R | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as COSV61520990; called by mutect2, varscan2
- SNAPC4 | c.1717G>C p.V573L | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.437); catalogued as rs1247498292; called by muse, varscan2
- SNX25 | c.2498A>G p.D833G | Missense Mutation (SNP) | VAF 52/228 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.516); catalogued as rs1268315021; called by muse, varscan2
- SPG21 | c.367C>T p.H123Y | Missense Mutation (SNP) | VAF 81/297 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs1344716790; called by muse, mutect2, varscan2
- SPOCD1 | c.1095G>T p.E365D | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV99929552; called by muse, mutect2, varscan2
- SPTB | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 74/432 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV101072364; called by muse, mutect2, varscan2
- TLN2 | c.878G>T p.S293I | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV60890974; called by muse, mutect2, varscan2
- TMEM132C | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.239); catalogued as rs550902946, COSV70672170; called by muse, mutect2, varscan2
- TNF | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 43/245 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV101403146; called by muse, mutect2, varscan2
- TRHR | c.255C>A p.D85E | Missense Mutation (SNP) | VAF 59/402 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV61233223; called by muse, mutect2, varscan2
- TRIM51 | c.944C>A p.P315H | Missense Mutation (SNP) | VAF 38/261 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV55267506; called by muse, mutect2, varscan2
- TRIO | c.7471G>T p.A2491S | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.262); catalogued as rs770576249; called by muse, mutect2, varscan2
- TRPC4 | c.820G>T p.D274Y | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV58998250, COSV59008794; called by muse, mutect2, varscan2
- TTN | c.61235A>T p.Y20412F (on ENST00000591111; = p.Y12988F on NM_003319.4) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | PolyPhen benign (0.003); catalogued as COSV60382227; called by muse, mutect2, varscan2
- UGT2B4 | c.254A>T p.E85V | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.827); catalogued as rs778962190; called by muse, mutect2, varscan2
- UNC13A | c.3022T>A p.Y1008N | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53204042; called by muse, mutect2, varscan2
- VPS13C | c.6355A>T p.S2119C (on ENST00000644861 / NM_020821.3; = p.S2076C on NM_017684.5) | Missense Mutation (SNP) | VAF 51/226 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV51140439; called by muse, mutect2, varscan2
- WDR87 | c.2491G>T p.A831S | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.086); catalogued as COSV58193583; called by muse, mutect2, varscan2
- ZC3HAV1 | c.2600G>T p.C867F | Missense Mutation (SNP) | VAF 54/286 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.194); catalogued as rs749513554, COSV54299027; called by muse, mutect2, varscan2
- ZNF331 | c.61del p.A21Pfs*3 | Frame Shift Del (DEL) | VAF 17/129 reads (13%) | catalogued as COSV99468182; called by mutect2, pindel*, varscan2
- ZNF462 | c.5285G>T p.R1762L | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV52937108; called by muse, mutect2, varscan2
- ZNF536 | c.1946A>G p.H649R | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62831725; called by muse, mutect2, varscan2
- ZNF843 | c.541G>T p.V181F | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV59847629; called by muse, mutect2, varscan2
- ZNF98 | c.720C>G p.C240W | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99078221; called by muse, mutect2, varscan2
- ABCA2 | c.7306G>T p.D2436Y (on ENST00000614293; = p.D2406Y on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 99/305 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- ABCA7 | c.5571-1G>T p.X1857_splice | Splice Site (SNP) | VAF 16/95 reads (17%) | called by muse, mutect2, varscan2
- ABCB5 | c.1525G>T p.E509* (on ENST00000404938 / NM_001163941.2; = p.E64* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 54/173 reads (31%) | called by muse, mutect2, varscan2
- ABCC12 | c.3715-1G>T p.X1239_splice | Splice Site (SNP) | VAF 23/113 reads (20%) | called by muse, mutect2, varscan2
- AC011448.1 | c.711del p.H238Tfs*23 | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | called by mutect2, pindel, varscan2
- ACACB | c.88A>T p.K30* | Nonsense Mutation (SNP) | VAF 39/208 reads (19%) | called by muse, mutect2, varscan2
- ACY3 | c.698G>T p.R233L | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- ADAD1 | c.1073_1074del p.L358Pfs*5 | Frame Shift Del (DEL) | VAF 48/234 reads (21%) | called by pindel, varscan2
- ADAM19 | c.2482A>T p.T828S | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM19 | c.1208G>T p.C403F | Missense Mutation (SNP) | VAF 29/200 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ADAM2 | c.764C>A p.T255K | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADARB2 | c.1545C>A p.F515L | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ADCY7 | c.11A>T p.K4M | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- ADD1 | c.171G>T p.R57S | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ADGRA2 | c.3617G>T p.G1206V | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- ADGRV1 | c.12263A>T p.N4088I | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- ADGRV1 | c.15149A>T p.K5050M | Missense Mutation (SNP) | VAF 60/319 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ADRA2A | c.1292A>G p.Y431C | Missense Mutation (SNP) | VAF 65/393 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGTR2 | c.737A>G p.K246R | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- AIFM3 | c.790G>T p.V264L | Missense Mutation (SNP) | VAF 43/193 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- AKAP1 | c.2005A>T p.N669Y | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- AKR1B15 | c.151-2A>T p.X51_splice | Splice Site (SNP) | VAF 76/341 reads (22%) | called by muse, mutect2, varscan2
- ANKRD24 | c.896A>T p.Q299L | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ANKRD33B | c.110A>G p.Y37C | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ANO4 | c.502C>A p.P168T (on ENST00000392977 / NM_001286615.2; = p.P133T on NM_178826.4) | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- AP3S1 | c.94A>T p.I32F | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- ARHGAP10 | c.1790C>T p.P597L | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- ARHGAP33 | c.1868-1G>T p.X623_splice | Splice Site (SNP) | VAF 49/221 reads (22%) | called by muse, mutect2, varscan2
- ARSH | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASCC3 | c.2058G>T p.L686F | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- ASNSD1 | c.910G>T p.D304Y | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- ASTN1 | c.907G>C p.D303H | Missense Mutation (SNP) | VAF 36/253 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ASTN2 | c.2763del p.S922Afs*38 (on ENST00000313400 / NM_001365069.1; = p.S871Afs*38 on NM_014010.5) | Frame Shift Del (DEL) | VAF 33/170 reads (19%) | called by mutect2, pindel, varscan2
- ASXL1 | c.141-2A>T p.X47_splice | Splice Site (SNP) | VAF 62/191 reads (32%) | called by muse, varscan2
- ASXL1 | c.141-1G>T p.X47_splice | Splice Site (SNP) | VAF 63/192 reads (33%) | called by muse, mutect2, varscan2
- ATP2B2 | c.675C>A p.D225E | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATP6V0A1 | c.852G>T p.Q284H | Missense Mutation (SNP) | VAF 51/305 reads (17%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ATPSCKMT | c.292G>T p.G98W | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATXN3 | c.69G>T p.L23F | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- B4GALNT4 | c.770A>T p.H257L | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BAG4 | c.823A>G p.T275A | Missense Mutation (SNP) | VAF 61/477 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- BANK1 | c.341T>C p.L114S | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BCAR1 | c.1852G>T p.G618C | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- BTAF1 | c.1818G>T p.W606C | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- C2CD2 | c.178dup p.S60Ffs*42 | Frame Shift Ins (INS) | VAF 10/66 reads (15%) | called by mutect2, varscan2
- C3 | c.205C>G p.L69V | Missense Mutation (SNP) | VAF 94/488 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- C8B | c.1472A>C p.Q491P | Missense Mutation (SNP) | VAF 62/262 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- CACNA1D | c.5165G>T p.S1722I (on ENST00000350061 / NM_001128840.3; = p.S1742I on NM_000720.4) | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1G | c.85_100del p.G29Rfs*31 | Frame Shift Del (DEL) | VAF 35/216 reads (16%) | called by mutect2, pindel, varscan2
- CACNA2D4 | c.1789del p.E597Kfs*7 | Frame Shift Del (DEL) | VAF 26/104 reads (25%) | called by mutect2, pindel, varscan2
- CADM3 | c.808G>A p.E270K (on ENST00000368125 / NM_001127173.3; = p.E304K on NM_021189.5) | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CAMK2D | c.1120G>T p.D374Y | Missense Mutation (SNP) | VAF 47/218 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAND1 | c.3361-1G>T p.X1121_splice | Splice Site (SNP) | VAF 19/89 reads (21%) | called by muse, mutect2, varscan2
- CAPN6 | c.1916C>A p.T639N | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); called by muse, varscan2
- CAPS2 | c.737A>T p.E246V | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, varscan2
- CAPSL | c.439A>T p.K147* | Nonsense Mutation (SNP) | VAF 34/168 reads (20%) | called by muse, mutect2, varscan2
- CASC3 | c.856G>T p.G286C | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- CASD1 | c.1316A>T p.Q439L | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CCDC32 | c.566A>T p.Y189F | Missense Mutation (SNP) | VAF 50/243 reads (21%) | PolyPhen benign (0.302); called by muse, mutect2, varscan2
- CCDC42 | c.741C>A p.N247K | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by mutect2, varscan2
- CCNL2 | c.1376A>G p.H459R | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD37 | c.658C>G p.P220A | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.187); called by muse, mutect2
- CDC42BPA | c.4520G>A p.R1507K (on ENST00000334218 / NM_001366019.2; = p.R1494K on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- CDH24 | c.164A>T p.E55V | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDK5RAP2 | c.5675G>T p.G1892V | Missense Mutation (SNP) | VAF 55/235 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CELF3 | c.368A>G p.E123G | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CENPE | c.1207A>G p.T403A | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- CFAP251 | c.2535G>T p.Q845H | Missense Mutation (SNP) | VAF 43/238 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, varscan2
- CFAP46 | c.4577G>T p.G1526V | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP54 | c.5883T>A p.F1961L | Missense Mutation (SNP) | VAF 55/341 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CHAF1B | c.356G>A p.W119* | Nonsense Mutation (SNP) | VAF 28/160 reads (18%) | called by muse, mutect2, varscan2
- CLDN19 | c.626+7C>A | Splice Region (SNP) | VAF 42/158 reads (27%) | called by muse, mutect2, varscan2
- CLEC12A | c.411G>T p.W137C | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CMTR2 | c.1936C>T p.P646S | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COA3 | c.41G>T p.R14L | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- COG2 | c.1380G>T p.E460D | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2
- COL12A1 | c.2229G>A p.W743* | Nonsense Mutation (SNP) | VAF 44/205 reads (21%) | called by muse, mutect2, varscan2
- COL6A2 | c.2119C>A p.L707I | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COMP | c.474C>A p.Y158* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- COPS7B | c.607A>T p.N203Y | Missense Mutation (SNP) | VAF 41/207 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CPS1 | c.1546T>A p.C516S | Missense Mutation (SNP) | VAF 53/279 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRACD | c.1126G>T p.E376* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2
- CREB3L3 | c.1309C>A p.L437M | Missense Mutation (SNP) | VAF 46/192 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- CREBBP | c.6266T>G p.I2089S | Missense Mutation (SNP) | VAF 120/494 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CRP | c.460G>T p.G154W | Missense Mutation (SNP) | VAF 61/372 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD3 | c.2188G>A p.G730R (on ENST00000297405 / NM_001363185.1; = p.G626R on NM_052900.3) | Missense Mutation (SNP) | VAF 75/253 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSPG5 | c.1384A>T p.K462* | Nonsense Mutation (SNP) | VAF 40/216 reads (19%) | called by muse, mutect2, varscan2
- CSRNP1 | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUX1 | c.4211G>T p.S1404I | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CYP4F22 | c.184C>A p.P62T | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- CYTL1 | c.343T>A p.L115M | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- DACT1 | c.1116G>T p.R372S | Missense Mutation (SNP) | VAF 53/290 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DDX60L | c.3799G>T p.G1267W | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DEFA6 | c.227G>A p.R76K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (1); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- DGKI | c.2302G>T p.A768S | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DHDH | c.686G>T p.S229I | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DISC1 | c.1166G>T p.S389I | Missense Mutation (SNP) | VAF 64/347 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- DLGAP2 | c.2452G>T p.V818L | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DLX6 | c.233C>G p.A78G | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, varscan2
- DMP1 | c.1350G>T p.E450D | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- DMRT1 | c.910G>C p.V304L | Missense Mutation (SNP) | VAF 69/349 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DMRT3 | c.1157C>G p.P386R | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.795); called by muse, mutect2
- DNAAF1 | c.1267C>A p.L423M | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- DNAH10 | c.2399G>T p.R800L (on ENST00000409039; = p.R739L on NM_207437.3) | Missense Mutation (SNP) | VAF 33/194 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- DNAH11 | c.8960C>A p.P2987Q | Missense Mutation (SNP) | VAF 77/232 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH14 | c.10309-4_10309delinsTTTTC p.X3437_splice (on ENST00000445597; = p.X4445_splice on NM_001367479.1) | Splice Site (ONP) | VAF 8/99 reads (8%) | called by pindel, varscan2*
- DNAH5 | c.13434C>A p.H4478Q | Missense Mutation (SNP) | VAF 65/293 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.041); called by muse, varscan2
- DOCK3 | c.4167G>T p.R1389S | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- DSCAM | c.2087C>A p.P696Q | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- DSCAM | c.1946A>C p.D649A | Missense Mutation (SNP) | VAF 53/358 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ECM1 | c.1550C>T p.A517V | Missense Mutation (SNP) | VAF 77/258 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- EEF1AKNMT | c.769A>T p.S257C (on ENST00000361735 / NM_015935.5; = p.S171C on NM_014955.3) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- ENAM | c.123A>T p.P41= | Splice Region (SNP) | VAF 65/291 reads (22%) | called by muse, mutect2, varscan2
- ENPP2 | c.2314A>T p.I772F (on ENST00000075322 / NM_001040092.3; = p.I824F on NM_006209.5) | Missense Mutation (SNP) | VAF 71/235 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- ENTHD1 | c.401A>G p.E134G | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- EPB41L2 | c.1214G>T p.G405V | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPB42 | c.485A>T p.Q162L (on ENST00000441366 / NM_001114134.2; = p.Q192L on NM_000119.3) | Missense Mutation (SNP) | VAF 77/317 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- EPHB1 | c.2431G>A p.G811R | Missense Mutation (SNP) | VAF 58/241 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHB2 | c.2953G>T p.E985* (on ENST00000400191 / NM_001309193.2; = p.E986* on NM_004442.7) | Nonsense Mutation (SNP) | VAF 61/303 reads (20%) | called by muse, mutect2, varscan2
- ERLEC1 | c.1339G>T p.V447L | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT tolerated (0.96); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- F5 | c.6187G>A p.V2063I | Missense Mutation (SNP) | VAF 59/449 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- FAM20B | c.271A>T p.M91L | Missense Mutation (SNP) | VAF 35/251 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM47A | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- FAM78B | c.394T>A p.S132T | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- FBXO4 | c.527A>T p.E176V | Missense Mutation (SNP) | VAF 38/201 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FGA | c.1813G>T p.D605Y | Missense Mutation (SNP) | VAF 54/269 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- FGFR1 | c.2409G>T p.E803D (on ENST00000447712 / NM_023110.3; = p.E801D on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT tolerated (0.99); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FGG | c.483C>G p.C161W | Missense Mutation (SNP) | VAF 75/398 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLG | c.7532G>T p.R2511I | Missense Mutation (SNP) | VAF 67/506 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- FLG2 | c.5266C>A p.H1756N | Missense Mutation (SNP) | VAF 42/304 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- FMO2 | c.320A>T p.Q107L | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- FOLH1 | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- FRMPD2 | c.173G>T p.C58F | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- FSCB | c.503C>A p.S168Y | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- FSIP2 | c.12227C>T p.A4076V | Missense Mutation (SNP) | VAF 47/190 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- GAD2 | c.1461C>A p.N487K | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GALNT13 | c.981G>T p.W327C | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- GALNT14 | c.1635G>T p.Q545H | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GART | c.1397G>T p.C466F | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- GATA4 | c.217G>T p.G73W | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- GDF10 | c.821C>A p.P274H | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- GDF6 | c.1358del p.G453Afs*41 | Frame Shift Del (DEL) | VAF 42/242 reads (17%) | called by mutect2, pindel, varscan2
- GET3 | c.20G>C p.G7A | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GFY | c.574G>T p.V192F | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GJA8 | c.53C>A p.S18Y | Missense Mutation (SNP) | VAF 96/317 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GLDC | c.287C>A p.P96H | Missense Mutation (SNP) | VAF 81/480 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLMN | c.1632A>T p.E544D | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GTPBP3 | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 40/209 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2
- GYS2 | c.1801T>G p.L601V | Missense Mutation (SNP) | VAF 55/207 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GZMB | c.575C>A p.P192Q | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- H2AC11 | c.29A>T p.K10I | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.489); called by muse, varscan2
- HIPK1 | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 54/327 reads (17%) | called by muse, mutect2, varscan2
- HMCN2 | c.14348C>G p.P4783R | Missense Mutation (SNP) | VAF 21/225 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- HNRNPCL1 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 51/205 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- HSPB3 | c.406G>C p.D136H | Missense Mutation (SNP) | VAF 87/438 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSPH1 | c.2453G>T p.G818V | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- IGF2BP1 | c.1644G>T p.M548I | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGFN1 | c.1261G>T p.G421C (on ENST00000295591 / NM_001367841.1; = p.G2878C on NM_001164586.2) | Missense Mutation (SNP) | VAF 50/298 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- IGFN1 | c.2122C>A p.H708N (on ENST00000295591 / NM_001367841.1; = p.H3165N on NM_001164586.2) | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- IGHV1-46 | c.114G>T p.K38N | Missense Mutation (SNP) | VAF 76/343 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- IGKV1D-8 | c.31G>T p.G11W | Missense Mutation (SNP) | VAF 39/268 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- IL12A | c.421-4C>G | Splice Region (SNP) | VAF 61/263 reads (23%) | called by muse, mutect2, varscan2
- IL22 | c.509T>C p.L170P | Missense Mutation (SNP) | VAF 31/171 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IL3 | c.113T>A p.M38K | Missense Mutation (SNP) | VAF 38/268 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.036); called by muse, mutect2
- INPP5D | c.448C>G p.P150A (on ENST00000445964 / NM_001017915.3; = p.P149A on NM_005541.5) | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- INSL3 | c.391T>A p.Y131N | Missense Mutation (SNP) | VAF 45/238 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- INTS1 | c.2898G>T p.Q966H | Missense Mutation (SNP) | VAF 69/216 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- INTS3 | c.2487G>T p.Q829H | Missense Mutation (SNP) | VAF 36/259 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ITGA4 | c.111C>G p.D37E | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITGAX | c.74A>T p.E25V | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- JMJD1C | c.5862A>C p.Q1954H | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KAT6B | c.6072G>C p.Q2024H | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KCNB2 | c.1679G>C p.C560S | Missense Mutation (SNP) | VAF 75/245 reads (31%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNH4 | c.1831G>T p.A611S | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNJ13 | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- KDM4B | c.2671G>C p.E891Q | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- KDM7A | c.2375G>T p.G792V | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- KDM7A | c.2375-1G>T p.X792_splice | Splice Site (SNP) | VAF 35/166 reads (21%) | called by muse, mutect2, varscan2
- KIAA2026 | c.4096G>T p.G1366W | Missense Mutation (SNP) | VAF 55/283 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- KIF13A | c.3355A>G p.K1119E | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- KIF21A | c.926G>T p.S309I | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIR3DL3 | c.380T>A p.L127Q | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.428); called by muse, varscan2
- KLF4 | c.678G>T p.M226I | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHL31 | c.850T>A p.C284S | Missense Mutation (SNP) | VAF 63/206 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KLHL6 | c.1261G>T p.G421C | Missense Mutation (SNP) | VAF 84/457 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMA2 | c.1709G>T p.S570I | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- LETM2 | c.48-1G>T p.X16_splice | Splice Site (SNP) | VAF 15/83 reads (18%) | called by muse, mutect2
- LINGO2 | c.1692T>G p.F564L | Missense Mutation (SNP) | VAF 47/226 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- LMX1A | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.608); called by muse, mutect2
- LRRC46 | c.760C>A p.P254T | Missense Mutation (SNP) | VAF 49/310 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRTOMT | c.279del p.I94Lfs*5 | Frame Shift Del (DEL) | VAF 37/238 reads (16%) | called by mutect2, pindel, varscan2
- LSM3 | c.76G>T p.D26Y | Missense Mutation (SNP) | VAF 40/230 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MACF1 | c.19362G>C p.W6454C (on ENST00000372915; = p.W4499C on NM_012090.5) | Missense Mutation (SNP) | VAF 29/170 reads (17%) | called by muse, mutect2, varscan2
- MAGEA11 | c.955C>A p.L319M | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MAGEB3 | c.878C>A p.A293D | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MAIP1 | c.646G>T p.E216* | Nonsense Mutation (SNP) | VAF 41/151 reads (27%) | called by muse, mutect2, varscan2
- MAP7D3 | c.974C>A p.A325E | Missense Mutation (SNP) | VAF 48/141 reads (34%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- MAPT | c.684G>T p.M228I (on ENST00000262410 / NM_001377265.1; = p.M153I on NM_016835.4) | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MARCHF9 | c.532A>G p.T178A | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- MASP1 | c.865G>T p.G289C | Missense Mutation (SNP) | VAF 72/341 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAU2 | c.1084C>A p.Q362K | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- MDN1 | c.515G>T p.C172F | Missense Mutation (SNP) | VAF 58/239 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- MED13 | c.5783-1G>T p.X1928_splice | Splice Site (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
- MED13 | c.1091G>T p.G364V | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MED16 | c.1353+1G>A p.X451_splice | Splice Site (SNP) | VAF 18/85 reads (21%) | called by muse, mutect2, varscan2
- MED25 | c.278A>T p.E93V | Missense Mutation (SNP) | VAF 82/439 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- MGAM | c.3723C>A p.Y1241* | Nonsense Mutation (SNP) | VAF 53/225 reads (24%) | called by muse, mutect2, varscan2
- MLIP | c.1007C>A p.P336Q | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MLYCD | c.400G>T p.V134L | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- MMP17 | c.1246G>T p.G416* | Nonsense Mutation (SNP) | VAF 33/163 reads (20%) | called by muse, mutect2, varscan2
- MOS | c.213dup p.G72Wfs*35 | Frame Shift Ins (INS) | VAF 28/183 reads (15%) | called by mutect2, pindel, varscan2
- MPHOSPH8 | c.1369del p.E457Kfs*22 | Frame Shift Del (DEL) | VAF 14/83 reads (17%) | called by mutect2, pindel, varscan2
- MROH5 | c.1442T>A p.L481H | Missense Mutation (SNP) | VAF 65/214 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MROH9 | c.1668G>T p.Q556H | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.758); called by muse, mutect2
- MS4A4E | c.307C>A p.Q103K | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.035); called by muse, varscan2
- MTMR11 | c.1290G>T p.E430D (on ENST00000439741 / NM_001145862.2; = p.E358D on NM_181873.3) | Missense Mutation (SNP) | VAF 46/274 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- MUC12 | c.12844C>A p.P4282T (on ENST00000379442; = p.P4139T on NM_001164462.1) | Missense Mutation (SNP) | VAF 53/736 reads (7%) | SIFT tolerated (0.18); called by muse, mutect2
- MUC16 | c.39907C>A p.P13303T | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT tolerated, low confidence (0.76); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- MUC16 | c.38126dup p.N12709Kfs*68 | Frame Shift Ins (INS) | VAF 31/182 reads (17%) | called by mutect2, pindel, varscan2
- MUC16 | c.18544G>C p.G6182R | Missense Mutation (SNP) | VAF 49/255 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- MUC16 | c.16318G>T p.V5440F | Missense Mutation (SNP) | VAF 36/268 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MUC16 | c.11823A>T p.K3941N | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- MXRA8 | c.521T>C p.L174P | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.243); called by muse, mutect2
- MYCBP2 | c.1904-1G>T p.X635_splice (on ENST00000357337; = p.X673_splice on NM_015057.5) | Splice Site (SNP) | VAF 18/66 reads (27%) | called by muse, mutect2
- MYH8 | c.1037C>A p.P346H | Missense Mutation (SNP) | VAF 64/266 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- MYO1H | c.1573G>T p.G525* | Nonsense Mutation (SNP) | VAF 17/106 reads (16%) | called by muse, mutect2, varscan2
- MYOF | c.1141G>A p.V381I | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- MYPN | c.2573A>T p.Q858L | Missense Mutation (SNP) | VAF 60/282 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- NDST3 | c.1714C>A p.L572I | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- NEDD4 | c.3239A>T p.Y1080F (on ENST00000508342 / NM_001284338.1; = p.Y661F on NM_006154.4) | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NELL2 | c.1190del p.G397Vfs*20 | Frame Shift Del (DEL) | VAF 28/176 reads (16%) | called by mutect2, pindel
- NEUROG1 | c.70G>T p.G24C | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NEXMIF | c.3362G>C p.R1121P | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- NEXMIF | c.530G>T p.C177F | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- NFE2L1 | c.1775C>T p.P592L | Missense Mutation (SNP) | VAF 24/273 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.03); called by muse, mutect2
- NIBAN3 | c.1648-2A>T p.X550_splice | Splice Site (SNP) | VAF 8/36 reads (22%) | called by muse, varscan2
- NLRP4 | c.788G>T p.S263I | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP4 | c.1215G>T p.E405D | Missense Mutation (SNP) | VAF 33/207 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- NNT | c.2869A>G p.K957E | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- NPHS1 | c.624C>A p.S208R | Missense Mutation (SNP) | VAF 52/321 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- NRAS | c.352T>C p.C118R | Missense Mutation (SNP) | VAF 63/320 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- NRF1 | c.1054G>T p.A352S | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUP133 | c.2991G>T p.E997D | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NXPH2 | c.460G>T p.G154C | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OBI1 | c.994A>T p.S332C | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OGDHL | c.364C>G p.R122G | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OIT3 | c.760G>A p.V254M | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- OR11H2 | c.692G>C p.G231A (on ENST00000556246; = p.G242A on NM_001197287.1) | Missense Mutation (SNP) | VAF 56/523 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR2B6 | c.261C>A p.S87R | Missense Mutation (SNP) | VAF 72/244 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, varscan2
- OR2B6 | c.316G>T p.A106S | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.075); called by muse, varscan2
- OR2T3 | c.171G>T p.E57D | Missense Mutation (SNP) | VAF 28/240 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR2T33 | c.445C>A p.L149M | Missense Mutation (SNP) | VAF 36/532 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.901); called by muse, mutect2
- OR4C46 | c.59A>T p.K20M | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- OR52D1 | c.43T>A p.F15I | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, varscan2
- OR5B3 | c.811dup p.M271Nfs*19 | Frame Shift Ins (INS) | VAF 39/267 reads (15%) | called by pindel, varscan2*
- OR5M8 | c.541C>A p.P181T | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- OR6A2 | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 50/215 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR8A1 | c.309C>A p.F103L | Missense Mutation (SNP) | VAF 64/221 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- OR9Q1 | c.680G>A p.G227E | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, varscan2
- OTOGL | c.6871G>T p.A2291S (on ENST00000547103; = p.A2282S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.62); called by muse, varscan2
- PAMR1 | c.15C>A p.C5* | Nonsense Mutation (SNP) | VAF 33/186 reads (18%) | called by muse, mutect2, varscan2
- PCDH10 | c.1327C>A p.L443I | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCDH15 | c.1996A>T p.T666S | Missense Mutation (SNP) | VAF 53/230 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PCDHB16 | c.1309A>T p.I437L | Missense Mutation (SNP) | VAF 66/340 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCDHGA5 | c.1613G>A p.G538E | Missense Mutation (SNP) | VAF 67/319 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGA8 | c.1712G>T p.G571V | Missense Mutation (SNP) | VAF 50/330 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- PCSK5 | c.3143-1G>A p.X1048_splice | Splice Site (SNP) | VAF 13/55 reads (24%) | called by muse, mutect2, varscan2
- PDCD11 | c.3707G>T p.R1236L | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- PDCL3 | c.52G>T p.G18C | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDIA6 | c.998G>T p.G333V | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDPN | c.326C>A p.S109Y (on ENST00000621990; = p.S185Y on NM_006474.4) | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PEBP4 | c.571G>T p.A191S | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2
- PEG3 | c.2867del p.P956Lfs*189 | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | called by mutect2, pindel, varscan2
- PHAX | c.616A>T p.R206W | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PHGDH | c.816G>T p.L272F | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PIEZO2 | c.3580G>C p.D1194H | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- PLA2G4D | c.101T>A p.L34Q | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PLA2G4E | c.381G>T p.Q127H | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- PLOD3 | c.1614+3G>T | Splice Region (SNP) | VAF 32/139 reads (23%) | called by muse, mutect2, varscan2
- PLXNA4 | c.2021G>C p.W674S | Missense Mutation (SNP) | VAF 39/247 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PNLIPRP1 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 16/286 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PNPLA6 | c.3946G>T p.E1316* (on ENST00000414982 / NM_001166111.2; = p.E1268* on NM_006702.5) | Nonsense Mutation (SNP) | VAF 81/404 reads (20%) | called by muse, mutect2, varscan2
- POLR3B | c.141T>A p.F47L | Missense Mutation (SNP) | VAF 12/281 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- PPFIA2 | c.577del p.E193Sfs*3 | Frame Shift Del (DEL) | VAF 12/102 reads (12%) | called by mutect2, pindel
- PRKG1 | c.178G>T p.A60S | Missense Mutation (SNP) | VAF 58/282 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PRR27 | c.144dup p.P49Tfs*21 | Frame Shift Ins (INS) | VAF 13/58 reads (22%) | called by mutect2, pindel, varscan2
- PRR35 | c.1012C>A p.L338M | Missense Mutation (SNP) | VAF 48/248 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- PRR36 | c.2752C>T p.P918S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.02); called by muse, mutect2, varscan2
- PSG7 | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 42/312 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- RAB11FIP2 | c.855A>C p.Q285H | Missense Mutation (SNP) | VAF 47/203 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- RAB11FIP4 | c.989G>T p.R330L | Missense Mutation (SNP) | VAF 53/326 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- RAB3GAP1 | c.1911dup p.P638Sfs*19 | Frame Shift Ins (INS) | VAF 52/274 reads (19%) | called by mutect2, pindel, varscan2
- RAB3GAP2 | c.3748C>G p.Q1250E | Missense Mutation (SNP) | VAF 67/431 reads (16%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- RASAL3 | c.2609G>T p.R870L | Missense Mutation (SNP) | VAF 60/276 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- RBM48 | c.1017+1G>A p.X339_splice | Splice Site (SNP) | VAF 28/176 reads (16%) | called by muse, mutect2, varscan2
- RELN | c.1443A>T p.G481= | Splice Region (SNP) | VAF 36/214 reads (17%) | called by muse, mutect2, varscan2
- RGL1 | c.792G>T p.R264S (on ENST00000360851 / NM_001297672.2; = p.R299S on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 116/333 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RGS11 | c.954G>C p.M318I (on ENST00000397770 / NM_183337.3; = p.M297I on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- RGS12 | c.3234+1G>T p.X1078_splice | Splice Site (SNP) | VAF 22/86 reads (26%) | called by muse, mutect2, varscan2
- RHOJ | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 59/275 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RIF1 | c.4715G>T p.W1572L | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RNF103 | c.966G>T p.E322D | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ROCK1 | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ROCK1 | c.94-1G>T p.X32_splice | Splice Site (SNP) | VAF 16/101 reads (16%) | called by muse, mutect2, varscan2
- ROS1 | c.5149A>G p.T1717A | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- RPE | c.347G>C p.G116A (on ENST00000359429 / NM_001318926.1; = p.G66A on NM_006916.2) | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- RPP40 | c.77A>T p.K26M | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2
- RPS15 | c.3+3G>T | Splice Region (SNP) | VAF 76/327 reads (23%) | called by muse, mutect2, varscan2
- RPS6KB2 | c.309+4A>C | Splice Region (SNP) | VAF 36/150 reads (24%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.1245G>T p.Q415H (on ENST00000265814 / NM_001198628.1; = p.Q388H on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/362 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- RYR2 | c.571T>C p.Y191H | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- RYR2 | c.692G>T p.G231V | Missense Mutation (SNP) | VAF 50/276 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- RYR2 | c.5023G>T p.A1675S | Missense Mutation (SNP) | VAF 45/238 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- RYR3 | c.3053G>T p.R1018L | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- SAMSN1 | c.688A>T p.K230* | Nonsense Mutation (SNP) | VAF 61/307 reads (20%) | called by muse, mutect2, varscan2
- SBK1 | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 69/430 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- SEL1L2 | c.1045G>T p.A349S | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- SERPINE1 | c.799G>T p.E267* | Nonsense Mutation (SNP) | VAF 69/365 reads (19%) | called by muse, mutect2, varscan2
- SETBP1 | c.4054G>C p.E1352Q | Missense Mutation (SNP) | VAF 85/302 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- SHISA6 | c.1370C>A p.T457N (on ENST00000409168 / NM_001173461.1; = p.T508N on NM_207386.4) | Missense Mutation (SNP) | VAF 49/239 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- SHPRH | c.4057G>A p.D1353N (on ENST00000275233 / NM_001042683.3; = p.D1357N on NM_173082.3) | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SIGLEC10 | c.1606C>T p.Q536* | Nonsense Mutation (SNP) | VAF 54/310 reads (17%) | called by muse, mutect2, varscan2
- SIGLEC12 | c.1230G>T p.R410S (on ENST00000291707 / NM_053003.4; = p.R292S on NM_033329.2) | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.18); called by muse, mutect2
- SIGLEC6 | c.604A>G p.I202V | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- SLC22A24 | c.1118A>T p.H373L | Missense Mutation (SNP) | VAF 37/210 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- SLC36A1 | c.958G>T p.G320C | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- SLC38A10 | c.2065+2T>A p.X689_splice (on ENST00000374759 / NM_001037984.3; = p.G689= on NM_138570.4) | Splice Site (SNP) | VAF 7/119 reads (6%) | called by muse, mutect2
- SLC39A12 | c.56G>T p.S19I | Missense Mutation (SNP) | VAF 42/244 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLCO2B1 | c.1322G>T p.G441V | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.173); called by muse, mutect2
- SLIT2 | c.2341C>A p.L781I | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SMARCAL1 | c.679G>T p.G227W | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- SMCO2 | c.325A>C p.T109P | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.264); called by muse, mutect2
- SOCS7 | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- SOX7 | c.791A>T p.Q264L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SP1 | c.232A>T p.S78C (on ENST00000327443 / NM_138473.3; = p.S71C on NM_003109.1) | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- SPARCL1 | c.813C>G p.N271K | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPATA31A1 | c.3409A>T p.R1137W | Missense Mutation (SNP) | VAF 99/456 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- SPI1 | c.481C>G p.P161A | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2
- SPTA1 | c.1211G>A p.G404D | Missense Mutation (SNP) | VAF 99/646 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- SPTAN1 | c.4878G>C p.E1626D | Missense Mutation (SNP) | VAF 53/256 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SRCAP | c.9277G>C p.D3093H | Missense Mutation (SNP) | VAF 8/153 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- ST6GAL2 | c.501G>T p.Q167H | Missense Mutation (SNP) | VAF 47/240 reads (20%) | PolyPhen benign (0.135); called by muse, mutect2, varscan2
- ST6GALNAC6 | c.442G>T p.G148C | Missense Mutation (SNP) | VAF 69/315 reads (22%) | PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- STAB1 | c.3112G>T p.D1038Y | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- STAB2 | c.2750C>A p.P917H | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- STRN4 | c.1745G>T p.C582F | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- STXBP5L | c.2135C>A p.S712Y | Missense Mutation (SNP) | VAF 38/220 reads (17%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- STYXL1 | c.12G>C p.L4F | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SYT6 | c.1014G>T p.E338D (on ENST00000610222 / NM_001366225.1; = p.E253D on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- TACR3 | c.515G>T p.S172I | Missense Mutation (SNP) | VAF 64/300 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TAF1L | c.2330C>A p.P777Q | Missense Mutation (SNP) | VAF 57/428 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- TARM1 | c.707dup p.N236Kfs*6 (on ENST00000616041 / NM_001330650.1; = p.N228Kfs*6 on NM_001135686.3) | Frame Shift Ins (INS) | VAF 22/111 reads (20%) | called by mutect2, pindel, varscan2
- TBCD | c.1687A>G p.M563V | Missense Mutation (SNP) | VAF 36/288 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- TBRG1 | c.104G>T p.R35L | Missense Mutation (SNP) | VAF 68/254 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- TBX15 | c.1061C>A p.T354N (on ENST00000369429 / NM_001330677.2; = p.T248N on NM_152380.3) | Missense Mutation (SNP) | VAF 70/319 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- TCIRG1 | c.2356G>T p.A786S | Missense Mutation (SNP) | VAF 107/475 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- TDRD12 | c.1448A>G p.Y483C | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TEAD2 | c.593G>T p.G198V | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- TENM2 | c.3457T>C p.C1153R (on ENST00000518659 / NM_001122679.2; = p.C921R on NM_001080428.3) | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TEX37 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TFB2M | c.569A>T p.K190I | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TGM4 | c.1539G>T p.Q513H | Missense Mutation (SNP) | VAF 48/262 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.119); called by mutect2, varscan2
- THSD1 | c.1568T>C p.I523T | Missense Mutation (SNP) | VAF 52/185 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- THSD7B | c.742T>G p.W248G | Missense Mutation (SNP) | VAF 64/278 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLN1 | c.3242G>T p.G1081V | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- TMPRSS15 | c.2985T>A p.C995* | Nonsense Mutation (SNP) | VAF 73/439 reads (17%) | called by muse, mutect2, varscan2
- TNS1 | c.1622C>G p.T541S | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.86); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- TRAV14DV4 | c.62C>A p.A21D | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TRAV41 | c.8A>T p.K3M | Missense Mutation (SNP) | VAF 56/220 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- TRHDE | c.943G>T p.G315* | Nonsense Mutation (SNP) | VAF 52/350 reads (15%) | called by muse, mutect2, varscan2
- TRIM49B | c.882A>T p.E294D | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- TRIM67 | c.890C>A p.A297D | Missense Mutation (SNP) | VAF 36/220 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- TRIML2 | c.556A>T p.S186C | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TRPM2 | c.3493G>T p.D1165Y | Missense Mutation (SNP) | VAF 47/231 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- TTBK1 | c.133T>A p.F45I | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TTC13 | c.1936del p.A646Pfs*8 | Frame Shift Del (DEL) | VAF 18/130 reads (14%) | called by mutect2, pindel*, varscan2
- TTC22 | c.131G>T p.R44L | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TTLL5 | c.3540G>T p.Q1180H | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.154); called by muse, mutect2
- TTN | c.101581T>C p.S33861P (on ENST00000591111; = p.S26437P on NM_003319.4) | Missense Mutation (SNP) | VAF 37/233 reads (16%) | PolyPhen benign (0.284); called by muse, mutect2, varscan2
- TTN | c.77125A>C p.K25709Q (on ENST00000591111; = p.K18285Q on NM_003319.4) | Missense Mutation (SNP) | VAF 49/291 reads (17%) | PolyPhen benign (0.012); called by muse, mutect2, varscan2
- UBXN4 | c.397A>T p.T133S | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- UGT3A2 | c.98G>T p.G33V | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- UNC80 | c.1386C>A p.H462Q | Missense Mutation (SNP) | VAF 53/316 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- UPRT | c.889G>C p.A297P | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- USH2A | c.14471C>T p.T4824I | Missense Mutation (SNP) | VAF 84/463 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- USP1 | c.874T>C p.S292P | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- USP24 | c.3064C>G p.L1022V | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- USP24 | c.1249A>G p.S417G | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- USP29 | c.2558G>T p.W853L | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP36 | c.1177C>T p.Q393* | Nonsense Mutation (SNP) | VAF 35/191 reads (18%) | called by muse, mutect2, varscan2
- USP9X | c.2350G>A p.D784N | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2
- VCAM1 | c.1417A>T p.T473S | Missense Mutation (SNP) | VAF 48/213 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- VCAN | c.10055G>T p.C3352F | Missense Mutation (SNP) | VAF 56/306 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VSTM2B | c.415G>T p.E139* | Nonsense Mutation (SNP) | VAF 78/358 reads (22%) | called by muse, mutect2, varscan2
- VWA5B2 | c.567G>T p.E189D | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- WASHC2C | c.2203G>C p.A735P | Missense Mutation (SNP) | VAF 45/322 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- WDFY3 | c.9446G>T p.R3149L | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- WDFY4 | c.2134G>T p.A712S | Missense Mutation (SNP) | VAF 59/258 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- WDR87 | c.6903G>T p.E2301D | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.14); called by muse, mutect2
- XIRP1 | c.4291C>T p.L1431F | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.193); called by muse, varscan2
- XIRP2 | c.128C>A p.S43Y (on ENST00000628543; = p.S218Y on NM_152381.6) | Missense Mutation (SNP) | VAF 34/210 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- XPNPEP1 | c.1477G>T p.G493C | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZC3H4 | c.3325C>T p.P1109S | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZFC3H1 | c.5878A>T p.R1960* | Nonsense Mutation (SNP) | VAF 29/140 reads (21%) | called by muse, mutect2, varscan2
- ZFP42 | c.368T>A p.M123K | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0.014); called by mutect2, varscan2
- ZFPM1 | c.65G>C p.R22T | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- ZNF114 | c.92A>T p.Y31F | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- ZNF148 | c.248A>G p.H83R | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- ZNF169 | c.445C>G p.P149A | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT tolerated (0.78); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF43 | c.1036G>C p.E346Q | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- ZNF534 | c.1231G>T p.A411S (on ENST00000332323 / NM_001143939.3; = p.A398S on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- ZNF536 | c.2630del p.S877Ffs*9 | Frame Shift Del (DEL) | VAF 25/130 reads (19%) | called by mutect2, pindel, varscan2
- ZNF598 | c.1955G>A p.G652E | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.969); called by muse, varscan2
- ZNF622 | c.607G>T p.E203* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2
- ZNF667 | c.317G>T p.S106I | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF708 | c.99G>T p.M33I | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- ZNF721 | c.782G>T p.G261V (on ENST00000338977; = p.G273V on NM_133474.4) | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF777 | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 37/217 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF780B | c.1448G>T p.S483I | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF804A | c.350T>A p.L117Q | Missense Mutation (SNP) | VAF 29/232 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF99 | c.2468G>T p.G823V | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF99 | c.2137G>C p.A713P | Missense Mutation (SNP) | VAF 48/278 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAM21 | c.1272C>A p.S424= | Silent (SNP) | VAF 61/368 reads (17%) | called by muse, mutect2, varscan2
- ADAMTS12 | c.2998C>A p.R1000= | Silent (SNP) | VAF 62/288 reads (22%) | called by muse, mutect2, varscan2
- ADAMTS14 | c.333T>A p.T111= | Silent (SNP) | VAF 76/465 reads (16%) | called by muse, mutect2, varscan2
- ADCY1 | c.456C>A p.A152= | Silent (SNP) | VAF 44/214 reads (21%) | called by muse, mutect2, varscan2
- ADGRA2 | c.1890G>T p.P630= | Silent (SNP) | VAF 56/384 reads (15%) | catalogued as COSV100178600; called by muse, mutect2, varscan2
- ADGRB1 | c.1065A>T p.P355= | Silent (SNP) | VAF 15/51 reads (29%) | called by muse, mutect2, varscan2
- ADGRF4 | c.906G>T p.L302= | Silent (SNP) | VAF 49/128 reads (38%) | called by muse, mutect2, varscan2
- ADGRL3 | c.2847G>C p.T949= (on ENST00000506720 / NM_001322402.2; = p.T881= on NM_015236.6) | Silent (SNP) | VAF 40/201 reads (20%) | catalogued as COSV101547134; called by muse, mutect2, varscan2
- ADPRHL1 | c.891G>T p.R297= | Silent (SNP) | VAF 32/123 reads (26%) | catalogued as COSV100733322; called by muse, mutect2, varscan2
- ALG3 | c.1107C>A p.P369= | Silent (SNP) | VAF 44/189 reads (23%) | called by muse, mutect2, varscan2
- ANGPT4 | c.1440C>G p.R480= | Silent (SNP) | VAF 58/212 reads (27%) | called by muse, mutect2, varscan2
- ANKRD55 | c.564C>T p.P188= | Silent (SNP) | VAF 62/284 reads (22%) | called by muse, mutect2, varscan2
- ARHGAP19 | c.648C>T p.T216= | Silent (SNP) | VAF 50/239 reads (21%) | called by muse, mutect2, varscan2
- ARNTL2 | c.423G>T p.A141= | Silent (SNP) | VAF 23/143 reads (16%) | called by muse, mutect2, varscan2
- ATOH7 | c.126C>A p.R42= | Silent (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2, varscan2
- ATP2B2 | c.2667G>T p.T889= (on ENST00000352432; = p.T855= on NM_001683.5) | Silent (SNP) | VAF 39/212 reads (18%) | catalogued as COSV59490628; called by muse, mutect2, varscan2
- BACH2 | c.1282C>A p.R428= | Silent (SNP) | VAF 22/92 reads (24%) | called by muse, mutect2
- BMPER | c.354C>A p.S118= | Silent (SNP) | VAF 93/442 reads (21%) | called by muse, mutect2, varscan2
- C2orf16 | c.1872A>G p.S624= | Silent (SNP) | VAF 31/118 reads (26%) | called by muse, mutect2, varscan2
- C3orf80 | c.360C>G p.P120= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV100426014; called by muse, mutect2, varscan2
- CACNA1B | c.4569C>A p.I1523= | Silent (SNP) | VAF 23/130 reads (18%) | catalogued as COSV53127018; called by muse, mutect2, varscan2
- CAPN11 | c.2052G>A p.L684= | Silent (SNP) | VAF 50/267 reads (19%) | called by muse, mutect2, varscan2
- CARD10 | c.1917G>T p.G639= | Silent (SNP) | VAF 38/135 reads (28%) | catalogued as COSV52654643; called by muse, mutect2, varscan2
- CAV3 | c.342C>A p.I114= | Silent (SNP) | VAF 51/279 reads (18%) | called by muse, mutect2, varscan2
- CBLIF | c.87C>A p.P29= | Silent (SNP) | VAF 62/372 reads (17%) | called by muse, mutect2, varscan2
- CCDC80 | c.1182C>T p.H394= | Silent (SNP) | VAF 30/160 reads (19%) | called by muse, mutect2, varscan2
- CCDC88C | c.2304C>T p.N768= | Silent (SNP) | VAF 30/166 reads (18%) | called by muse, varscan2
- CCR8 | c.711C>A p.I237= | Silent (SNP) | VAF 42/174 reads (24%) | called by muse, mutect2, varscan2
- CDK5RAP2 | c.5676C>T p.G1892= | Silent (SNP) | VAF 54/234 reads (23%) | catalogued as rs1416016572; called by muse, mutect2, varscan2
- CEACAM20 | c.1383G>T p.V461= | Silent (SNP) | VAF 43/120 reads (36%) | called by muse, mutect2, varscan2
- CELSR1 | c.1719G>A p.T573= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs759822220, COSV53092949; called by muse, mutect2, varscan2
- CENPF | c.8397C>T p.I2799= | Silent (SNP) | VAF 19/178 reads (11%) | called by muse, mutect2, varscan2
- CEP131 | c.3048G>C p.R1016= (on ENST00000269392 / NM_001319228.2; = p.R1013= on NM_014984.4) | Silent (SNP) | VAF 34/118 reads (29%) | called by muse, mutect2, varscan2
- CFAP46 | c.7896C>G p.L2632= | Silent (SNP) | VAF 19/79 reads (24%) | called by muse, mutect2, varscan2
- CFAP47 | c.2766C>A p.G922= | Silent (SNP) | VAF 40/107 reads (37%) | called by muse, mutect2, varscan2
- CKAP5 | c.3972G>A p.K1324= | Silent (SNP) | VAF 34/236 reads (14%) | called by muse, mutect2, varscan2
- CLEC5A | c.117C>A p.T39= | Silent (SNP) | VAF 76/420 reads (18%) | called by muse, mutect2, varscan2
- CNTN5 | c.1035A>T p.A345= | Silent (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2, varscan2
- COL18A1 | c.1524A>T p.S508= (on ENST00000359759 / NM_130444.3; = p.S273= on NM_030582.4) | Silent (SNP) | VAF 75/360 reads (21%) | called by muse, mutect2, varscan2
- COL27A1 | c.969A>G p.L323= | Silent (SNP) | VAF 22/125 reads (18%) | called by muse, mutect2, varscan2
- COL3A1 | c.2511C>A p.G837= | Silent (SNP) | VAF 59/369 reads (16%) | catalogued as rs1157152697; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL7A1 | c.5457C>A p.L1819= | Silent (SNP) | VAF 50/265 reads (19%) | called by muse, mutect2, varscan2
- CREG2 | c.87C>A p.A29= | Silent (SNP) | VAF 16/87 reads (18%) | called by muse, mutect2, varscan2
- CSMD3 | c.7773G>T p.V2591= (on ENST00000297405 / NM_001363185.1; = p.V2487= on NM_052900.3) | Silent (SNP) | VAF 52/336 reads (15%) | catalogued as rs746284745; called by muse, mutect2, varscan2
- CTSA | c.1104A>G p.L368= | Silent (SNP) | VAF 169/454 reads (37%) | called by muse, mutect2, varscan2
- CYP4F12 | c.1389A>T p.A463= | Silent (SNP) | VAF 27/157 reads (17%) | called by muse, mutect2, varscan2
- DACH2 | c.594C>A p.T198= | Silent (SNP) | VAF 26/94 reads (28%) | called by muse, mutect2, varscan2
- DLL3 | c.645G>A p.E215= | Silent (SNP) | VAF 27/158 reads (17%) | called by muse, mutect2, varscan2
- DNAH3 | c.5397T>A p.I1799= | Silent (SNP) | VAF 46/192 reads (24%) | called by muse, mutect2, varscan2
- DNAH9 | c.600C>A p.S200= | Silent (SNP) | VAF 14/44 reads (32%) | called by muse, varscan2
- DNMT3B | c.2487G>T p.L829= | Silent (SNP) | VAF 126/349 reads (36%) | called by muse, mutect2, varscan2
- DPP10 | c.816G>A p.A272= | Silent (SNP) | VAF 28/171 reads (16%) | catalogued as rs573090640, COSV59691032; called by muse, mutect2, varscan2
- DPYSL4 | c.1329T>A p.P443= | Silent (SNP) | VAF 32/187 reads (17%) | called by muse, mutect2, varscan2
- DZIP1L | c.960A>G p.A320= | Silent (SNP) | VAF 18/134 reads (13%) | called by muse, mutect2
- ELP4 | c.1056G>T p.R352= (on ENST00000350638; = p.R351= on NM_019040.5) | Silent (SNP) | VAF 19/111 reads (17%) | catalogued as rs747866123; called by muse, mutect2, varscan2
- EMC10 | c.786G>T p.R262= | Silent (SNP) | VAF 9/50 reads (18%) | called by muse, varscan2
- EPRS1 | c.2067A>T p.P689= | Silent (SNP) | VAF 34/162 reads (21%) | catalogued as rs986960085; called by muse, mutect2, varscan2
- ERC2 | c.2283G>A p.Q761= | Silent (SNP) | VAF 25/110 reads (23%) | called by muse, mutect2, varscan2
- FAM186B | c.2265C>A p.R755= | Silent (SNP) | VAF 39/232 reads (17%) | catalogued as COSV57723518; called by muse, mutect2, varscan2
- FANCE | c.1359G>T p.V453= | Silent (SNP) | VAF 159/468 reads (34%) | called by muse, varscan2
- FCRL5 | c.2562G>T p.G854= | Silent (SNP) | VAF 27/198 reads (14%) | called by muse, mutect2, varscan2
- FKBP8 | c.390G>A p.S130= | Silent (SNP) | VAF 23/156 reads (15%) | catalogued as rs1174850375; called by muse, mutect2, varscan2
- FREM3 | c.1665T>A p.T555= | Silent (SNP) | VAF 28/139 reads (20%) | called by muse, mutect2, varscan2
- FRMPD1 | c.2295C>A p.G765= | Silent (SNP) | VAF 34/180 reads (19%) | called by muse, mutect2, varscan2
- FTMT | c.525G>T p.L175= | Silent (SNP) | VAF 67/359 reads (19%) | catalogued as COSV100360216; called by muse, mutect2, varscan2
- FZD1 | c.657G>T p.P219= | Silent (SNP) | VAF 35/178 reads (20%) | called by muse, mutect2, varscan2
- GAK | c.3132A>T p.A1044= | Silent (SNP) | VAF 22/110 reads (20%) | called by muse, varscan2
- GP9 | c.93C>G p.T31= | Silent (SNP) | VAF 64/287 reads (22%) | called by muse, mutect2, varscan2
- GPR33 | c.294T>A p.T98= | Silent (SNP) | VAF 61/351 reads (17%) | called by muse, mutect2, varscan2
- GPR45 | c.255C>A p.L85= | Silent (SNP) | VAF 53/228 reads (23%) | called by muse, mutect2, varscan2
- GTPBP3 | c.933G>T p.V311= | Silent (SNP) | VAF 42/220 reads (19%) | called by muse, mutect2
- HAVCR2 | c.798C>A p.T266= | Silent (SNP) | VAF 41/199 reads (21%) | catalogued as COSV100324966; called by muse, mutect2, varscan2
- HCAR3 | c.525T>C p.N175= | Silent (SNP) | VAF 48/308 reads (16%) | called by muse, mutect2
- HEATR6 | c.3372C>T p.S1124= | Silent (SNP) | VAF 45/279 reads (16%) | catalogued as rs758429792, COSV51745110; called by muse, mutect2, varscan2
- HVCN1 | c.807T>C p.L269= | Silent (SNP) | VAF 44/224 reads (20%) | called by muse, mutect2, varscan2
- IFNW1 | c.402G>T p.G134= | Silent (SNP) | VAF 38/186 reads (20%) | catalogued as COSV66521965; called by muse, mutect2, varscan2
- IGKV2-30 | c.102C>A p.T34= | Silent (SNP) | VAF 35/129 reads (27%) | called by mutect2, varscan2
- IGKV2D-29 | c.184C>T p.L62= | Silent (SNP) | VAF 34/255 reads (13%) | called by muse, mutect2
- IL21R | c.948G>T p.V316= | Silent (SNP) | VAF 30/136 reads (22%) | called by muse, mutect2, varscan2
- IL22 | c.510G>T p.L170= | Silent (SNP) | VAF 30/172 reads (17%) | called by muse, mutect2, varscan2
- IPO8 | c.3009G>T p.T1003= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as COSV99805443; called by muse, mutect2, varscan2
- ITGA1 | c.3168A>G p.R1056= | Silent (SNP) | VAF 28/125 reads (22%) | called by muse, varscan2
- KHDC1L | c.126G>T p.T42= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV64893413; called by muse, varscan2
- KIAA0825 | c.1575A>T p.T525= | Silent (SNP) | VAF 91/447 reads (20%) | called by muse, mutect2, varscan2
- KIF1A | c.741G>C p.V247= | Silent (SNP) | VAF 25/112 reads (22%) | called by muse, mutect2, varscan2
- KIF6 | c.1497T>C p.D499= | Silent (SNP) | VAF 80/256 reads (31%) | called by muse, mutect2, varscan2
- KPNB1 | c.594C>A p.L198= | Silent (SNP) | VAF 38/137 reads (28%) | catalogued as COSV99268508; called by muse, mutect2, varscan2
- KRT71 | c.163C>A p.R55= | Silent (SNP) | VAF 36/212 reads (17%) | catalogued as COSV57291326; called by muse, mutect2, varscan2
- L1CAM | c.2121G>T p.V707= | Silent (SNP) | VAF 29/71 reads (41%) | called by muse, mutect2, varscan2
- LCA5 | c.112C>T p.L38= | Silent (SNP) | VAF 52/197 reads (26%) | called by muse, varscan2
- LHX5 | c.999G>T p.P333= | Silent (SNP) | VAF 46/255 reads (18%) | catalogued as rs755471088; called by muse, mutect2, varscan2
- LILRA1 | c.78C>A p.L26= | Silent (SNP) | VAF 13/86 reads (15%) | called by muse, mutect2, varscan2
- LSR | c.69C>A p.S23= | Silent (SNP) | VAF 55/293 reads (19%) | catalogued as COSV61555866; called by muse, mutect2, varscan2
- LVRN | c.900G>T p.T300= | Silent (SNP) | VAF 44/254 reads (17%) | catalogued as COSV100773328; called by muse, mutect2, varscan2
- MAG | c.867C>A p.L289= | Silent (SNP) | VAF 12/80 reads (15%) | called by muse, mutect2, varscan2
- MAPT | c.1668C>A p.G556= (on ENST00000262410 / NM_001377265.1; = p.G164= on NM_005910.5) | Silent (SNP) | VAF 80/422 reads (19%) | called by muse, mutect2, varscan2
- MCAT | c.177G>T p.P59= | Silent (SNP) | VAF 33/75 reads (44%) | called by muse, mutect2, varscan2
- MED12L | c.5578C>A p.R1860= | Silent (SNP) | VAF 84/491 reads (17%) | catalogued as COSV56392429; called by muse, mutect2, varscan2
- MMRN1 | c.2052T>A p.A684= | Silent (SNP) | VAF 22/125 reads (18%) | called by muse, mutect2, varscan2
- MPDZ | c.5172C>T p.L1724= | Silent (SNP) | VAF 32/218 reads (15%) | called by muse, mutect2, varscan2
- MSX1 | c.276G>T p.S92= | Silent (SNP) | VAF 22/110 reads (20%) | called by muse, mutect2, varscan2
- MUC16 | c.39906G>A p.Q13302= | Silent (SNP) | VAF 22/150 reads (15%) | catalogued as rs760037509; called by muse, mutect2, varscan2
- MUC16 | c.29547G>C p.V9849= | Silent (SNP) | VAF 30/185 reads (16%) | called by muse, mutect2, varscan2
- MUC16 | c.10203C>A p.S3401= | Silent (SNP) | VAF 30/197 reads (15%) | called by muse, mutect2, varscan2
- MUC16 | c.3747C>A p.P1249= | Silent (SNP) | VAF 41/213 reads (19%) | called by muse, mutect2, varscan2
- MUC5B | c.4350G>T p.T1450= | Silent (SNP) | VAF 17/74 reads (23%) | called by muse, mutect2, varscan2
- MYH13 | c.1677T>G p.L559= | Silent (SNP) | VAF 47/160 reads (29%) | called by muse, mutect2, varscan2
- MYO3A | c.609G>A p.L203= | Silent (SNP) | VAF 68/389 reads (17%) | catalogued as COSV99780858; called by muse, mutect2, varscan2
- NCAN | c.2127G>T p.G709= | Silent (SNP) | VAF 63/332 reads (19%) | called by muse, mutect2, varscan2
- NIBAN2 | c.2076G>T p.S692= | Silent (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- NOS2 | c.171G>C p.P57= | Silent (SNP) | VAF 28/136 reads (21%) | catalogued as rs773527134, COSV100569762, COSV58223187; called by muse, mutect2, varscan2
- NRXN1 | c.3735C>T p.I1245= | Silent (SNP) | VAF 41/238 reads (17%) | catalogued as COSV100640788; called by muse, mutect2, varscan2
- NRXN1 | c.3183G>C p.R1061= | Silent (SNP) | VAF 22/88 reads (25%) | called by muse, mutect2, varscan2
- NRXN1 | c.2239C>A p.R747= | Silent (SNP) | VAF 53/330 reads (16%) | catalogued as COSV100457069, COSV58452930; called by muse, mutect2, varscan2
- OIT3 | c.759G>A p.L253= | Silent (SNP) | VAF 26/122 reads (21%) | catalogued as COSV61826935; called by muse, mutect2, varscan2
- OR10A6 | c.699G>C p.G233= | Silent (SNP) | VAF 58/166 reads (35%) | catalogued as rs267603210; called by muse, mutect2, varscan2
- OR2AP1 | c.168C>A p.P56= | Silent (SNP) | VAF 38/179 reads (21%) | catalogued as rs1385285034; called by muse, mutect2, varscan2
- OR2G6 | c.792T>C p.N264= | Silent (SNP) | VAF 51/196 reads (26%) | catalogued as rs758478274, COSV100598343; called by muse, mutect2, varscan2
- OR4S1 | c.720A>T p.S240= | Silent (SNP) | VAF 34/149 reads (23%) | called by muse, mutect2, varscan2
- OR6C75 | c.111G>T p.V37= | Silent (SNP) | VAF 20/100 reads (20%) | called by muse, mutect2, varscan2
- OR6Q1 | c.123G>A p.L41= | Silent (SNP) | VAF 48/268 reads (18%) | called by muse, mutect2, varscan2
- OR7G1 | c.108G>T p.L36= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as rs528021653; called by muse, mutect2, varscan2
- OR9A4 | c.333G>A p.E111= | Silent (SNP) | VAF 63/268 reads (24%) | catalogued as rs782665501; called by muse, mutect2, varscan2
- OTOF | c.5028C>T p.R1676= (on ENST00000272371 / NM_194248.3; = p.R909= on NM_004802.4) | Silent (SNP) | VAF 40/191 reads (21%) | catalogued as rs765616249, COSV55501001; called by muse, mutect2, varscan2
- PCDH15 | c.837A>T p.P279= | Silent (SNP) | VAF 72/358 reads (20%) | called by muse, mutect2, varscan2
- PCDHB15 | c.1554G>T p.S518= | Silent (SNP) | VAF 111/555 reads (20%) | called by muse, mutect2, varscan2
- PCDHB8 | c.288G>C p.L96= | Silent (SNP) | VAF 30/236 reads (13%) | called by muse, mutect2, varscan2
- PCDHGA3 | c.102G>T p.S34= | Silent (SNP) | VAF 30/125 reads (24%) | called by muse, mutect2, varscan2
- PCDHGA5 | c.1764G>T p.V588= | Silent (SNP) | VAF 55/312 reads (18%) | called by muse, mutect2, varscan2
- PDZRN4 | c.483G>T p.G161= | Silent (SNP) | VAF 15/71 reads (21%) | called by muse, varscan2
- PHF3 | c.4437A>G p.Q1479= | Silent (SNP) | VAF 27/149 reads (18%) | catalogued as rs773121129, COSV50316747; called by muse, mutect2, varscan2
163 further variants in this file (0 protein-altering or splice-affecting, 48 silent, 115 other) are not listed here.
